Gene-level copy-number profile of tumor specimen C3N-01079-01 from CPTAC case C3N-01079, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G1.
Specimen C3N-01079-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e4d3c43-8b9d-4505-89c5-c245bcd7fe97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01079-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/da694f9a-0007-4e5e-9a94-1123690a32c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 23,951; copy number 2: 28,167; copy number 3: 6,215; copy number 4: 11; copy number 5: 24.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,823,159, 2 genes: PRAMEF1, LINC01784.
- chr1:12,838,125–12,928,253, 8 genes (within-gene range 0–1): PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr9:21,802,636–22,029,594, 7 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.
- chr17:18,450,244–18,475,920, 4 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–268,655, 22 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.2.
- chr2:186,590,056–186,695,287, 2 genes, copy number 5 (within-gene range 2–5): ITGAV, AC017101.1.

Autosomal genes at a single copy (total copy number 1): 23,948. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
